Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7828, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7828-01A (Primary Tumor).

Final Diagnosis

Left kidney, partial nephrectomy:

Papillary renal cell carcinoma, Fuhrman nuclear grade 3.

Tumor measures 3.5 cm in maximum dimension.

Tumor is confined to kidney, surgical margins of resection are free.

No lymphovascular invasion is identified.

Comment: This case corresponds to a pathological AJCC stage of T1a,NX.

Clinical Information

Left renal mass, .

Operating Room Consultation

Left partial nephrectomy. No ORC.

Gross Description

"A, Left partial nephrectomy." Received is a , 4.2 x 3.7 x 3.1 cm portion of kidney with attached perinephric fat. The resection margin will be inked black. The specimen has been previously sectioned to reveal a 3.5 x 2.7 cm pale tan, focally cystic mass. The mass grossly appears to abut the adjacent renal capsule. The Gerota's fascia overlying the mass will be inked orange. The mass grossly appears to come to within 0.6 cm of the resection margin. "A1-A2," mass with resection margin; "A3-A4," mass with adjacent perinephric fat and Gerota's fascia.

Source: NCI Genomic Data Commons file eecc00f3-9451-4cb3-afc3-7577a8adc6ff (TCGA-A4-7828.4B7B0802-70C4-4BA0-8370-BE06B0064BCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).